Gene-level copy-number profile of tumor specimen TCGA-EE-A184-06A from TCGA case TCGA-EE-A184, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.7 years (28,364 days).
Specimen TCGA-EE-A184-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.0aa97afc-8937-49c0-978e-116122c7d10a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A184-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/46be3036-fd7e-40b6-9ea5-c4e52459ca99

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,065; copy number 2: 38,672; copy number 3: 9,975; copy number 4: 2,848; copy number 5: 1,621; copy number 6: 159; copy number 7: 88; copy number 8: 200; copy number 9: 37; copy number 10: 39; copy number 11: 57; copy number 12: 34; copy number 13: 6; copy number 14: 3; copy number 16: 5; copy number 17: 1; copy number 18: 1; copy number 19: 3; copy number 21: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A184-06A-11D-A194-01): tumor purity 0.85, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,256 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,111,121–199,909,648, 591 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:214,943,123–221,840,717, 87 genes, copy number 5 (broad region; genes not listed).
- chr1:237,042,184–248,919,946, 274 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:4,012,708–4,147,429, 3 genes, copy number 8: AC025773.1, AC025187.1, LINC02063.
- chr5:9,628,997–13,032,886, 53 genes, copy number 5–10 (within-gene range 1–10): TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220.
- chr5:13,553,654–14,871,778, 14 genes, copy number 5–10 (within-gene range 4–10): NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2.
- chr5:15,384,220–15,496,353, 3 genes, copy number 5 (within-gene range 1–5): MARK2P5, AC114964.2, AC114964.1.
- chr5:16,373,361–20,937,800, 75 genes, copy number 6–18 (within-gene range 1–18) (broad region; genes not listed).
- chr5:30,545,177–36,347,157, 105 genes, copy number 5–19 (broad region; genes not listed).
- chr5:36,588,506–39,572,639, 54 genes, copy number 6–14: AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1.
- chr5:41,730,065–41,968,366, 9 genes, copy number 6 (within-gene range 2–6): OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr13:29,872,613–31,162,388, 35 genes, copy number 6–12 (within-gene range 3–12): LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1.
- chr13:34,262,863–40,921,774, 89 genes, copy number 5–17 (within-gene range 2–17) (broad region; genes not listed).
- chr13:41,955,808–42,003,637, 2 genes, copy number 6: VWA8-AS1, RPS28P8.
- chr13:42,043,727–42,071,093, 2 genes, copy number 6: AL157932.1, MAPK6P3.
- chr13:44,094,822–44,397,714, 9 genes, copy number 5 (within-gene range 1–5): LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2.
- chr13:70,107,213–70,171,738, 2 genes, copy number 5: ATXN8OS, AL160391.1.
- chr13:71,437,966–72,782,096, 15 genes, copy number 6–14 (within-gene range 4–14): DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3.
- chr13:73,100,575–74,565,445, 19 genes, copy number 5–21: FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr13:77,895,481–78,617,328, 10 genes, copy number 8 (within-gene range 4–8): EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54.
- chr13:89,833,157–90,535,080, 9 genes, copy number 7–11: RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049.
- chr13:91,272,081–91,354,579, 8 genes, copy number 6: PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:112,894,378–113,554,590, 27 genes, copy number 8 (within-gene range 1–8): MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1.
- chr20:30,214,765–43,389,041, 340 genes, copy number 5 (broad region; genes not listed).
- chr20:59,515,191–61,940,617, 25 genes, copy number 5 (within-gene range 4–5): AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.
- chr22:19,714,503–19,941,820, 9 genes, copy number 8: SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1.
- chr22:20,441,519–21,081,018, 39 genes, copy number 8 (within-gene range 4–8): KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4.
- chr22:22,219,647–23,164,350, 110 genes, copy number 5 (broad region; genes not listed).
- chr22:23,179,918–23,180,172, 1 gene, copy number 5: BCRP8.
- chr22:24,934,954–24,946,695, 1 gene, copy number 7: TMEM211.
- chr22:25,009,685–25,065,241, 4 genes, copy number 7: AL022323.2, AL022323.4, AL022323.1, AL022323.3.
- chr22:31,618,491–31,662,432, 1 gene, copy number 6 (within-gene range 1–6): PISD.
- chr22:31,676,256–32,498,829, 40 genes, copy number 6: PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1, AL008723.3, RFPL2, IGLCOR22-1, SLC5A4-AS1, SLC5A4, CPSF1P1, AL008723.2, AL021937.3, RFPL3, IGLCOR22-2, RFPL3S, AL021937.6, AL021937.5, AL021937.1, IGLVIVOR22-2, AL021937.4, AL021937.2, RTCB, BPIFC, FBXO7.
- chr22:32,583,300–32,584,204, 1 gene, copy number 6: SYN3-AS1.
- chr22:33,320,865–35,425,431, 28 genes, copy number 6–9: Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5.
- chr22:38,861,422–39,492,194, 30 genes, copy number 8 (within-gene range 4–8): CBX6, AL022318.5, AL022318.1, APOBEC3A, APOBEC3B, APOBEC3B-AS1, APOBEC3C, AL022318.4, APOBEC3D, APOBEC3F, AL022318.2, APOBEC3G, AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1.
- chr22:40,769,630–42,721,298, 92 genes, copy number 5–10 (broad region; genes not listed).
- chr22:46,244,011–47,261,007, 16 genes, copy number 5–12: CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1.
- chr22:48,403,462–48,489,324, 3 genes, copy number 5: Z72006.1, Z82249.1, Z84468.2.
- chr22:49,166,421–49,758,980, 15 genes, copy number 5–16: Z82202.2, RPL35P8, Z82202.1, AC207130.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, Z97192.4, AL023802.1, RN7SKP252, RPL5P35.

Autosomal genes at a single copy (total copy number 1): 3,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
